Somatic mutation profile of tumor specimen C3L-01311-01 (aliquot CPT0077770013) from CPTAC case C3L-01311, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 55.2 years (20,175 days).
Specimen C3L-01311-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 793ce8e1-132e-41a2-ba50-c4e136a70a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01311-31 (Blood Derived Normal), aliquot CPT0080090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91adeac8-afe2-4b12-96fb-5c7424dd6ba2

The open-access MAF lists 3,547 somatic variants for this specimen: 2,528 protein-altering or splice-affecting, 575 silent, 444 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,111, Silent 575, Nonsense Mutation 341, Intron 222, RNA 77, 3'UTR 77, Splice Site 31, 5'UTR 27, 5'Flank 27, Splice Region 25, 3'Flank 14, Frame Shift Ins 12.

Variants (750 of 3,547; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 60/179 reads (34%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 140/483 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- CYBB | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 108/415 reads (26%) | catalogued as rs886041192, CM960436, COSV66085069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.741C>T p.G247= (on ENST00000399959; = p.G248= on NM_001356.5) | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as rs1569238002, COSV67863076; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 53/200 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 155/446 reads (35%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDA | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs483352804, CM148958; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGF8 | c.346C>T p.R116* (on ENST00000344255 / NM_033164.4; = p.R98* on NM_006119.6) | Nonsense Mutation (SNP) | VAF 161/628 reads (26%) | catalogued as rs137852663, CM082676, CM104200, COSV60143465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 188/687 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs574132670, CM155651, COSV64701534, COSV64701602; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- MYO7A | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs201539845, CD951791, CM110685; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NDUFAF2 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 74/265 reads (28%) | catalogued as rs137852863, CM053986, COSV56942088; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NEB | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as rs1057517360, CM1413898; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 85/370 reads (23%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NUP88 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 41/127 reads (32%) | catalogued as rs774070092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 77/282 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PROS1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906674, CM108673, COSV67774997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 161/530 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTPN11 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 108/382 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs376607329; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 81/322 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- QRICH2 | c.3037C>T p.R1013* | Nonsense Mutation (SNP) | VAF 151/444 reads (34%) | catalogued as rs777214459; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4547C>T p.S1516L (on ENST00000303395 / NM_001202435.3; = p.S1505L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs139300715, CM024310, CM1511239, COSV57665028; ClinVar: uncertain significance / likely benign / likely pathogenic; called by muse, varscan2
- SMPX | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 88/278 reads (32%) | catalogued as rs387906707, CM112964; ClinVar: pathogenic; called by muse, varscan2
- TWNK | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 139/460 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs556445621, CM1411682, COSV99272667; ClinVar: likely benign / pathogenic; called by muse, mutect2, varscan2
- UBR4 | c.10388G>A p.R3463H | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747867083, COSV64398222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs1206591663, COSV54052428; called by muse, mutect2, varscan2
- A2ML1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142219499; ClinVar: likely benign; called by muse, mutect2, varscan2
- A3GALT2 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as rs867991028; called by muse, mutect2, varscan2
- ABCA10 | c.3867G>T p.E1289D | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as COSV104393422; called by muse, mutect2, varscan2
- ABCA12 | c.2682C>T p.L894= (on ENST00000272895 / NM_173076.3; = p.L576= on NM_015657.3) | Splice Region (SNP) | VAF 74/250 reads (30%) | catalogued as rs552554246, COSV99789742; called by muse, mutect2, varscan2
- ABCA13 | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 35/401 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1334169510; called by muse, mutect2
- ABCB1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 202/719 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55946143; called by muse, mutect2, varscan2
- ABCB5 | c.1621C>T p.R541* (on ENST00000404938 / NM_001163941.2; = p.R96* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 60/232 reads (26%) | catalogued as COSV51702825; called by muse, mutect2, varscan2
- ABCC2 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 58/680 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763988128, COSV64984835; called by muse, mutect2
- ABCG8 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs781002570, COSV55397240; called by muse, mutect2, varscan2
- ABHD18 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as rs1390095513; called by muse, mutect2
- ABHD18 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66293685, COSV66294022; called by muse, mutect2, varscan2
- ABI1 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61015312; called by muse, mutect2
- AC093155.3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs753328703; called by muse, mutect2, varscan2
- ACAP3 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61223726; called by muse, mutect2, varscan2
- ACBD3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 60/220 reads (27%) | catalogued as COSV64729752; called by muse, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACMSD | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs757421443, COSV51607251; called by muse, varscan2
- ACOT12 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs113234186, COSV56892781; called by muse, mutect2, varscan2
- ACOX3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs762558027, COSV62711619; called by muse, mutect2, varscan2
- ACTR10 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 12/224 reads (5%) | catalogued as rs1397422376, COSV54297993; called by muse, mutect2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTRT1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs138725538, COSV64418994; called by muse, mutect2, varscan2
- ADAMTS17 | c.520A>C p.S174R | Missense Mutation (SNP) | VAF 131/543 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs761591792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS4 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146858388; called by muse, mutect2, varscan2
- ADAMTS5 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs753190231, COSV53178906; called by muse, mutect2, varscan2
- ADAP1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs755612339; called by muse, varscan2
- ADCY10 | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as rs1279793150; called by muse, mutect2, varscan2
- ADGRA1 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV66925906; called by muse, mutect2, varscan2
- ADGRB2 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1281995077, COSV57077247; called by muse, mutect2, varscan2
- ADGRE2 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1440588897, COSV100216142; called by muse, mutect2, varscan2
- ADGRF5 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as COSV51932614; called by muse, varscan2
- ADGRV1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372147148, COSV101315539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs757860505, CM1514169, COSV67986933; called by muse, varscan2
- ADH4 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs557732938, COSV55500215; called by muse, mutect2, varscan2
- ADIPOR2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs200483941, COSV63946468; called by muse, mutect2, varscan2
- ADRA1B | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370209486, COSV60701675; called by muse, mutect2, varscan2
- AFF2 | c.3446C>T p.S1149L | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1341384078, COSV53975147; called by muse, mutect2, varscan2
- AFM | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56919193; called by mutect2, varscan2
- AGMO | c.735A>C p.K245N | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs768686109; called by muse, mutect2, varscan2
- AGO3 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1034258905; called by muse, mutect2
- AGO4 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV64616661; called by muse, mutect2, varscan2
- AGPAT4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57243767; called by muse, mutect2, varscan2
- AHCYL2 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs201615414, COSV61487208; called by muse, varscan2
- AHNAK2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.117); catalogued as rs192363522, COSV60924082; called by muse, mutect2, varscan2
- AK9 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868260985, COSV53419508; called by muse, mutect2, varscan2
- AKAP13 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs779495573, COSV100773513; called by muse, mutect2, varscan2
- AKAP8L | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs767032741, COSV68474469; called by muse, mutect2
- AKAP9 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as rs773523925, COSV100662872, COSV62343385; called by muse, mutect2
- AKNA | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs776996904; called by muse, mutect2, varscan2
- AL645922.1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 123/467 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as rs763450579, COSV54962560; called by muse, mutect2, varscan2
- AL645922.1 | c.3778G>T p.D1260Y | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64888379; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALDH1L2 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 89/328 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs138908674; called by muse, mutect2, varscan2
- ALDH5A1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs772361710, COSV100708811; called by muse, mutect2, varscan2
- ALKAL1 | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV62130126; called by muse, mutect2, varscan2
- ANAPC5 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55843265; called by muse, mutect2
- ANK2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 166/518 reads (32%) | catalogued as rs146907003, COSV52159416; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANK3 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376032920; called by mutect2, varscan2
- ANKMY2 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100187081; called by muse, mutect2, varscan2
- ANKRD10 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779123844, COSV57442692; called by muse, mutect2, varscan2
- ANKRD18A | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as rs1288728145; called by muse, mutect2, varscan2
- ANKRD30A | c.3184G>A p.E1062K (on ENST00000611781; = p.E1006K on NM_052997.2) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100654384; called by muse, mutect2, varscan2
- ANKRD30B | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs1177659977, COSV100744583; called by muse, mutect2, varscan2
- ANKRD30B | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.197); catalogued as COSV57703722; called by muse, mutect2, varscan2
- ANKRD30B | c.4117G>T p.E1373* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100271271, COSV57702532; called by muse, mutect2
- ANKRD34C | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV69855667; called by muse, mutect2, varscan2
- ANKRD36 | c.3174G>T p.E1058D | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV70401433; called by muse, mutect2, varscan2
- ANKRD36C | c.3481G>T p.E1161* | Nonsense Mutation (SNP) | VAF 24/323 reads (7%) | catalogued as COSV54756088; called by muse, mutect2
- ANKRD36C | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as rs772117678, COSV99754498; called by muse, mutect2, varscan2
- ANKRD50 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs371516395; called by muse, mutect2, varscan2
- ANKS1B | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs374815422, COSV61353917; called by muse, mutect2, varscan2
- ANLN | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs767615862, COSV56074340; called by muse, mutect2, varscan2
- ANP32E | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | catalogued as COSV58483736; called by muse, mutect2, varscan2
- ANPEP | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.23); catalogued as rs774559825, COSV55589577; called by muse, mutect2, varscan2
- AP1G1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | catalogued as COSV55490960; called by muse, mutect2
- AP1S2 | c.180-1G>T p.X60_splice | Splice Site (SNP) | VAF 50/285 reads (18%) | catalogued as COSV100236748; called by muse, mutect2, varscan2
- APAF1 | c.3238G>A p.D1080N (on ENST00000551964 / NM_181861.2; = p.D1026N on NM_001160.3) | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV59669801; called by muse, mutect2, varscan2
- APC | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 17/466 reads (4%) | catalogued as CM040672, COSV57347257; called by muse, mutect2
- APC | c.5912C>A p.S1971Y | Missense Mutation (SNP) | VAF 181/568 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754691867, CM044572, COSV57334200, COSV57362562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 45/146 reads (31%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- APP | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 181/625 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382239795, COSV60994133; called by muse, mutect2, varscan2
- APPL2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as rs1314012568, COSV51588026; called by muse, mutect2, varscan2
- ARFGEF1 | c.5320C>T p.R1774* | Nonsense Mutation (SNP) | VAF 49/160 reads (31%) | catalogued as COSV51588024; called by muse, mutect2, varscan2
- ARFGEF3 | c.6388C>A p.L2130I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52450738; called by muse, mutect2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | catalogued as rs1487117985, COSV64381180; called by muse, mutect2, varscan2
- ARHGAP30 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs754444804, COSV63514735; called by muse, mutect2, varscan2
- ARHGAP31 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 133/523 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775767431, COSV51789291, COSV51793206; called by muse, mutect2, varscan2
- ARHGAP5 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | catalogued as COSV61534005; called by muse, mutect2, varscan2
- ARHGAP9 | c.2014G>A p.E672K (on ENST00000393797 / NM_001319850.2; = p.E653K on NM_032496.4) | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.112); catalogued as COSV57357774; called by muse, varscan2
- ARHGAP9 | c.1846C>T p.R616W (on ENST00000393797 / NM_001319850.2; = p.R597W on NM_032496.4) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs747924330; called by muse, mutect2, varscan2
- ARHGEF16 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 65/293 reads (22%) | catalogued as rs777897887, COSV65683650; called by muse, mutect2, varscan2
- ARHGEF9 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99491780; called by muse, varscan2
- ARID2 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777576250, COSV57609462; called by muse, mutect2, varscan2
- ARL14EPL | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1282333524, COSV59948732; called by muse, mutect2, varscan2
- ARL9 | c.463C>T p.R155W (on ENST00000640821 / NM_001363794.2; = p.R13W on NM_206919.2) | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777668617, COSV63991277, COSV63991652; called by muse, mutect2, varscan2
- ARMC4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 96/304 reads (32%) | catalogued as rs752348839, COSV100536620, COSV59458741; called by muse, mutect2, varscan2
- ARMCX3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs372051555, COSV57871198; called by muse, mutect2, varscan2
- ART4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as rs3168583, COSV57451798; called by muse, mutect2, varscan2
- ASB15 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs1376721710, COSV51924653; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASNS | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1399973379, COSV99446363, COSV99446930; called by muse, mutect2, varscan2
- ASPHD1 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 48/168 reads (29%) | catalogued as COSV104394635; called by muse, mutect2, varscan2
- ASPM | c.4490G>T p.R1497I | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.348); catalogued as rs779743297; called by muse, mutect2, varscan2
- ASPM | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 117/437 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1038039573; called by mutect2, varscan2
- ATAD2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1270279267, COSV54880131, COSV54880435; called by muse, mutect2, varscan2
- ATAD3B | c.611G>A p.R204Q (on ENST00000308647; = p.R310Q on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs757282899; called by muse, mutect2, varscan2
- ATG2B | c.5428G>T p.E1810* | Nonsense Mutation (SNP) | VAF 45/154 reads (29%) | catalogued as COSV99952224; called by muse, mutect2, varscan2
- ATP10A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs201206599, COSV63512808; called by muse, mutect2, varscan2
- ATP4A | c.2420T>C p.V807A | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99382160; called by muse, mutect2
- ATP5PB | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs768759849, COSV71953320; called by muse, mutect2, varscan2
- ATP6V1A | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as COSV56361224; called by muse, mutect2, varscan2
- ATP7A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV58444929; called by muse, mutect2, varscan2
- ATP8A2 | c.3549G>T p.K1183N | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV54939053; called by muse, mutect2, varscan2
- ATRNL1 | c.3148G>T p.D1050Y | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV100369626; called by muse, mutect2, varscan2
- ATRX | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 45/156 reads (29%) | catalogued as rs1311466929, COSV64873935; called by muse, mutect2, varscan2
- AURKA | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 124/393 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373550419; called by muse, mutect2, varscan2
- AXIN1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV51984069; called by muse, mutect2, varscan2
- B3GALT1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 42/153 reads (27%) | catalogued as COSV59909606; called by muse, mutect2, varscan2
- B4GALT3 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.025); catalogued as rs528969895; called by muse, mutect2, varscan2
- BABAM1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs766735279, COSV53105514; called by muse, mutect2, varscan2
- BAIAP3 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567104517, COSV50104889; called by muse, mutect2, varscan2
- BANK1 | c.2139G>T p.M713I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV59842931, COSV59844962; called by muse, mutect2, varscan2
- BAZ1A | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.381); catalogued as rs138917569; called by muse, mutect2, varscan2
- BAZ2A | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as rs768952335; called by muse, mutect2, varscan2
- BBS5 | c.755C>A p.S252* | Nonsense Mutation (SNP) | VAF 12/302 reads (4%) | catalogued as COSV54753144; called by muse, mutect2
- BCAR3 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1218493045, COSV53074897; called by muse, mutect2
- BCAT2 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 53/144 reads (37%) | catalogued as rs139293308; called by muse, mutect2, varscan2
- BCLAF1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs1487882129, COSV50361469; called by muse, mutect2, varscan2
- BCLAF1 | c.1263A>C p.K421N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100786698; called by muse, mutect2, varscan2
- BCOR | c.4606G>A p.D1536N (on ENST00000378444 / NM_001123385.2; = p.D1502N on NM_017745.6) | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60710740, COSV60716315; called by muse, varscan2
- BCORL1 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as rs772509421, COSV54395933; called by muse, mutect2, varscan2
- BCS1L | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 210/728 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55306711; called by muse, mutect2, varscan2
- BDKRB2 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.132); catalogued as rs201521050; called by muse, mutect2, varscan2
- BEX5 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61328355; called by muse, mutect2, varscan2
- BHLHE22 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.105); catalogued as rs1375950161; called by muse, mutect2, varscan2
- BIRC6 | c.6871C>T p.R2291C | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771264582, COSV70196203, COSV70202819; called by muse, mutect2, varscan2
- BMP3 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51082268; called by muse, mutect2, varscan2
- BMP5 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 96/268 reads (36%) | catalogued as COSV63706517; called by muse, mutect2, varscan2
- BMPR2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs573463511; called by muse, mutect2, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 144/450 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BNIPL | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.878); catalogued as rs756845902; called by mutect2, varscan2
- BPIFA3 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64926054; called by muse, mutect2, varscan2
- BPTF | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58830634; called by muse, mutect2, varscan2
- BPTF | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs764527892, COSV58833907; called by mutect2, varscan2
- BRD1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs762230069, COSV53454612; called by muse, mutect2, varscan2
- BSN | c.6706G>A p.V2236M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774642445; called by muse, mutect2, varscan2
- BTG3 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs771256877; called by muse, mutect2, varscan2
- BUB1B | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 91/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349349252, COSV99807268; called by muse, mutect2, varscan2
- C11orf80 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs771347098, COSV60929254, COSV60931469; called by muse, mutect2, varscan2
- C12orf29 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 42/146 reads (29%) | catalogued as COSV63554430; called by muse, mutect2, varscan2
- C14orf39 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147627198, COSV58779891; called by muse, mutect2, varscan2
- C14orf39 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | catalogued as COSV100407132, COSV58781579; called by muse, mutect2, varscan2
- C16orf78 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54556148; called by muse, mutect2, varscan2
- C18orf63 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 51/209 reads (24%) | catalogued as rs571143284; called by muse, mutect2, varscan2
- C1QTNF8 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs145677284; called by muse, mutect2, varscan2
- C1orf141 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs1214656440, COSV63992367; called by muse, mutect2, varscan2
- C1orf146 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as COSV64860819; called by muse, mutect2, varscan2
- C20orf141 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV63027868; called by muse, mutect2
- C2CD3 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 45/198 reads (23%) | catalogued as rs760746206, COSV100486477, COSV58095811; called by muse, mutect2, varscan2
- C3 | c.3382G>T p.E1128* | Nonsense Mutation (SNP) | VAF 83/307 reads (27%) | catalogued as COSV55569757, COSV55570157, COSV99837235; called by muse, mutect2, varscan2
- C4B | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 230/717 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1438112943, COSV101426196; called by muse, mutect2, varscan2
- C4orf54 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1353578745, COSV72766678; called by muse, mutect2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 127/448 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C6orf58 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61666334; called by muse, mutect2, varscan2
- C7orf57 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs779873173; called by muse, mutect2, varscan2
- C9orf135 | c.285A>T p.E95D | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.921); catalogued as COSV65875291; called by muse, mutect2, varscan2
- CABS1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs540614090, COSV56733253; called by muse, mutect2, varscan2
- CACHD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 105/342 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.921); catalogued as rs1329242081, COSV51547183; called by muse, mutect2, varscan2
- CACNA1C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV59696193; called by muse, mutect2, varscan2
- CACNA1C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59695046; called by muse, mutect2
- CACNA1H | c.3580C>T p.R1194W | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1399681066; called by muse, mutect2, varscan2
- CACNA2D3 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 118/210 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs555199325, COSV55523079; called by muse, varscan2
- CACNG3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV50065182, COSV99135432; called by muse, mutect2, varscan2
- CADM4 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as COSV55929914; called by muse, mutect2
- CADPS | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs902090459, COSV51874317; called by muse, mutect2, varscan2
- CALCR | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.366); catalogued as COSV64006764; called by muse, mutect2, varscan2
- CALD1 | c.1451G>A p.R484Q (on ENST00000361675 / NM_033138.4; = p.R229Q on NM_004342.7) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.414); catalogued as rs200617975, COSV62647098, COSV62647237; called by muse, mutect2, varscan2
- CAMSAP1 | c.1047G>A p.A349= | Splice Region (SNP) | VAF 18/88 reads (20%) | catalogued as rs142430334; called by muse, mutect2, varscan2
- CAMSAP2 | c.1565C>A p.S522Y (on ENST00000236925 / NM_001297707.2; = p.S511Y on NM_203459.3) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1180021082; called by muse, mutect2, varscan2
- CAPN6 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100136678; called by muse, mutect2, varscan2
- CAPS2 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs1281844668; called by muse, varscan2
- CARF | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 83/273 reads (30%) | catalogued as COSV57547562; called by muse, mutect2, varscan2
- CASD1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51971469; called by muse, mutect2, varscan2
- CASP12 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs564091554, COSV100998306; called by muse, varscan2
- CASP12 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 20/151 reads (13%) | catalogued as COSV100998294; called by muse, varscan2
- CASP8AP2 | c.4623C>A p.F1541L | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99386807; called by muse, mutect2, varscan2
- CASQ2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 138/382 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as rs1557809802, COSV54770103; called by muse, mutect2, varscan2
- CATSPER3 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99253984; called by muse, mutect2, varscan2
- CAVIN4 | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1247178831, COSV56866765; called by muse, mutect2, varscan2
- CBLL1 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56028453, COSV99755862; called by muse, mutect2
- CCDC14 | c.1583T>G p.F528C (on ENST00000488653; = p.F480C on NM_022757.5) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1209461289; called by muse, mutect2, varscan2
- CCDC168 | c.20548G>A p.E6850K | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV59421006; called by muse, mutect2, varscan2
- CCDC168 | c.16684C>A p.L5562I | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV59418496; called by muse, mutect2
- CCDC168 | c.11448G>T p.K3816N | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1480172220, COSV59423601; called by muse, mutect2, varscan2
- CCDC168 | c.5986G>T p.E1996* | Nonsense Mutation (SNP) | VAF 40/168 reads (24%) | catalogued as COSV70554790; called by muse, mutect2, varscan2
- CCDC171 | c.650G>T p.R217I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV52633939; called by muse, mutect2, varscan2
- CCDC174 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs201187132; called by muse, mutect2, varscan2
- CCDC181 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 50/217 reads (23%) | catalogued as rs766836009, COSV63158080; called by muse, mutect2, varscan2
- CCDC198 | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99371312; called by muse, mutect2, varscan2
- CCDC54 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV53760178; called by muse, mutect2
- CCDC6 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as rs868314380; called by muse, mutect2, varscan2
- CCDC7 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV99511577; called by muse, mutect2, varscan2
- CCNA1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1273259772, COSV55222575; called by muse, mutect2, varscan2
- CCNDBP1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs776264677, COSV55747539; called by muse, mutect2, varscan2
- CCT2 | c.363del p.H122Ifs*6 | Frame Shift Del (DEL) | VAF 69/237 reads (29%) | catalogued as COSV100167761; called by mutect2, pindel, varscan2
- CCT2 | c.1143A>C p.Q381H | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.991); catalogued as COSV54741470; called by muse, mutect2, varscan2
- CCT6B | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs1244990017, COSV100030461; called by muse, mutect2, varscan2
- CD1D | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs182855664, COSV63808761; called by muse, mutect2, varscan2
- CD200R1 | c.427C>T p.R143C (on ENST00000471858 / NM_170780.3; = p.R166C on NM_138806.4) | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs550063106, COSV55602431; called by muse, mutect2, varscan2
- CD22 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs143516468; called by muse, mutect2, varscan2
- CD28 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.204); catalogued as rs200016310, COSV60730994; called by muse, mutect2, varscan2
- CDC73 | c.730-1G>T p.X244_splice | Splice Site (SNP) | VAF 87/311 reads (28%) | catalogued as COSV66467798; called by muse, mutect2, varscan2
- CDCA7 | c.905G>A p.R302Q (on ENST00000347703 / NM_145810.3; = p.R381Q on NM_031942.5) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs748528043, COSV60720069, COSV60720142; called by muse, mutect2, varscan2
- CDH23 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as rs374527066; called by muse, mutect2, varscan2
- CDK13 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs150957134, COSV51697681; called by muse, mutect2, varscan2
- CDX4 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 94/323 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs200133821; called by muse, mutect2, varscan2
- CEACAM20 | c.1614G>A p.T538= | Splice Region (SNP) | VAF 29/81 reads (36%) | catalogued as rs762179860, COSV57601271; called by muse, mutect2
- CEACAM20 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs756391229, COSV57602058; called by muse, mutect2, varscan2
- CEACAM7 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV50075162; called by muse, mutect2
- CELF4 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs150441111, COSV100612162; called by muse, mutect2, varscan2
- CELSR3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50872490, COSV51158577; called by muse, mutect2, varscan2
- CENPJ | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs758150747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP135 | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs768288451, COSV57263563; called by muse, mutect2, varscan2
- CEP152 | c.3910C>T p.R1304C (on ENST00000380950 / NM_001194998.2; = p.R1248C on NM_014985.4) | Missense Mutation (SNP) | VAF 190/627 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376099036, COSV100358385; called by muse, mutect2, varscan2
- CEP57 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 109/354 reads (31%) | catalogued as rs745587374, COSV57688150; called by muse, mutect2, varscan2
- CFAP100 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV61503470, COSV61504799; called by muse, mutect2, varscan2
- CFAP20 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 98/315 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1439539411; called by muse, mutect2, varscan2
- CFAP20DC | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.391); catalogued as rs1371813917; called by muse, mutect2, varscan2
- CFAP300 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs751349174, COSV71570599; called by muse, mutect2, varscan2
- CFAP44 | c.5197C>T p.R1733* | Nonsense Mutation (SNP) | VAF 111/334 reads (33%) | catalogued as rs764605240, COSV57661334; called by muse, mutect2, varscan2
- CFAP52 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs146937773; called by muse, mutect2, varscan2
- CFAP54 | c.5878G>T p.E1960* | Nonsense Mutation (SNP) | VAF 118/404 reads (29%) | catalogued as COSV61571501; called by muse, mutect2, varscan2
- CFAP58 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV57213484; called by muse, mutect2, varscan2
- CFAP61 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs760689597, COSV55620168, COSV55632747; called by muse, mutect2, varscan2
- CFHR2 | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1197201332; called by muse, mutect2, varscan2
- CHRM5 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs774588600, COSV67246946; called by muse, varscan2
- CHRM5 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs769593960; called by muse, varscan2
- CHRNA2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 182/536 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs372418511, COSV99532200; called by muse, mutect2, varscan2
- CHRNA4 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 196/607 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs765977956; called by muse, mutect2, varscan2
- CHSY3 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370639793; called by muse, mutect2, varscan2
- CHUK | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 138/421 reads (33%) | catalogued as rs373590755; called by muse, mutect2, varscan2
- CILP | c.3221A>G p.Y1074C | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336676063; called by muse, mutect2
- CILP | c.2348G>T p.R783I | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56021847; called by muse, mutect2, varscan2
- CILP2 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 51/174 reads (29%) | catalogued as rs763530960; called by muse, mutect2, varscan2
- CKAP5 | c.2379C>A p.F793L | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV100370334; called by muse, mutect2, varscan2
- CLCA2 | c.2471C>A p.S824* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as COSV100991797; called by muse, mutect2, varscan2
- CLCA4 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99760479; called by muse, mutect2, varscan2
- CLGN | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs139581390; called by muse, mutect2, varscan2
- CLHC1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 51/171 reads (30%) | catalogued as rs753530709, COSV68464143; called by muse, mutect2, varscan2
- CLK4 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV100309106; called by muse, mutect2, varscan2
- CLTCL1 | c.4314C>A p.F1438L | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.37); catalogued as COSV104371816; called by muse, mutect2, varscan2
- CLUL1 | c.381T>G p.I127M | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs758713595, COSV58112569; called by muse, mutect2, varscan2
- CMPK2 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 12/232 reads (5%) | catalogued as COSV56776223; called by muse, mutect2
- CMTR2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs960907780, COSV57605066; called by muse, mutect2, varscan2
- CNBD1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1330613877, COSV72916988; called by muse, mutect2
- CNBD1 | c.1260A>C p.K420N | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV73073150; called by muse, mutect2
- CNOT1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs371890421, COSV100408635; called by muse, mutect2, varscan2
- CNTN3 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV55161810, COSV99723580; called by muse, mutect2, varscan2
- CNTNAP5 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV70493925; called by muse, varscan2
- COL11A2 | c.2803G>T p.E935* (on ENST00000341947 / NM_080680.3; = p.E828* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 28/414 reads (7%) | catalogued as COSV100553563; called by muse, mutect2
- COL14A1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.998); catalogued as rs750355331, COSV52853130; called by muse, mutect2, varscan2
- COL19A1 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 89/368 reads (24%) | catalogued as rs866179157, COSV59586186; called by muse, mutect2, varscan2
- COL21A1 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 115/339 reads (34%) | catalogued as rs749557286, COSV55155216; called by muse, mutect2, varscan2
- COL21A1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs181443791; called by muse, mutect2, varscan2
- COL6A3 | c.6934G>T p.E2312* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | catalogued as COSV55083866; called by muse, mutect2
- COL6A6 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760929088, COSV62040954; called by muse, mutect2, varscan2
- COL6A6 | c.6179T>G p.F2060C | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV62021978; called by muse, mutect2, varscan2
- COMMD3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV64958918; called by muse, mutect2, varscan2
- COPB1 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182148424, COSV51448599, COSV99999434; called by muse, mutect2
- COPS4 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 16/208 reads (8%) | catalogued as COSV100018798; called by muse, mutect2
- CP | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 17/271 reads (6%) | catalogued as COSV52829905, COSV52830422; called by muse, mutect2
- CPAMD8 | c.4327G>A p.A1443T (on ENST00000651564; = p.A1396T on NM_015692.5) | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs780228887; called by muse, mutect2, varscan2
- CPB2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs376421547; called by muse, mutect2, varscan2
- CPSF6 | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57012046; called by muse, mutect2, varscan2
- CRACR2A | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs756529583; called by muse, mutect2, varscan2
- CRB1 | c.3301G>T p.E1101* | Nonsense Mutation (SNP) | VAF 153/578 reads (26%) | catalogued as COSV100957607, COSV66332650; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1400757152, COSV53232441; called by muse, mutect2, varscan2
- CSF2RB | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs146404001, COSV53257443; called by muse, mutect2, varscan2
- CSMD3 | c.8825C>A p.S2942Y (on ENST00000297405 / NM_001363185.1; = p.S2773Y on NM_052900.3) | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52173377; called by muse, mutect2
- CSMD3 | c.6691C>T p.R2231* (on ENST00000297405 / NM_001363185.1; = p.R2127* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | catalogued as rs751474008, COSV52093601, COSV52154452; called by muse, mutect2
- CSNK1A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV55792565; called by muse, mutect2, varscan2
- CSPP1 | c.2478G>T p.K826N (on ENST00000676605; = p.K785N on NM_024790.6) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs190028385, COSV51580095; called by muse, mutect2, varscan2
- CST1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs778452912, COSV100494321; called by muse, mutect2
- CST11 | c.387A>C p.K129N (on ENST00000377009 / NM_130794.2; = p.K94N on NM_080830.3) | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV65440450; called by muse, mutect2
- CTCF | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567610917, COSV50461678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs746832628, COSV57072983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 36/129 reads (28%) | catalogued as rs201498915, COSV57069365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNND2 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 166/497 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs868558083, COSV58866978; called by muse, mutect2, varscan2
- CTR9 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1391585643, COSV63728784; called by muse, mutect2
- CTSA | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 164/632 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV99510137; called by muse, mutect2, varscan2
- CTSV | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774981893, COSV52344228; called by muse, mutect2, varscan2
- CWF19L1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs771426135; called by muse, mutect2, varscan2
- CXCL2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV56021646, COSV99933208; called by muse, mutect2, varscan2
- CYBB | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 128/452 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV101059835, COSV99059637; called by muse, mutect2, varscan2
- CYFIP2 | c.1368G>T p.M456I | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100557293; called by muse, mutect2, varscan2
- CYP1A1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 113/433 reads (26%) | catalogued as COSV101122391, COSV65697031; called by muse, mutect2, varscan2
- CYP20A1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201088277, COSV61909261, COSV61909939; called by muse, varscan2
- CYP27C1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.269); catalogued as rs1193457558; called by muse, mutect2, varscan2
- CYP2J2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as rs899892667, COSV64605512; called by muse, mutect2
- CYP2R1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs61744571, COSV58126974; called by muse, mutect2, varscan2
- CYP2U1 | c.987G>T p.R329S | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs146484674; called by muse, mutect2, varscan2
- CYP7A1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56963098, COSV56964475; called by muse, mutect2, varscan2
- CYP8B1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs762230983, COSV60226483; called by muse, mutect2, varscan2
- DAAM1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs768979450; called by muse, mutect2, varscan2
- DAAM2 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776017051, COSV99224789; called by muse, mutect2, varscan2
- DACH2 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | catalogued as COSV64175104, COSV64177950; called by muse, mutect2, varscan2
- DAW1 | c.1051-1G>T p.X351_splice | Splice Site (SNP) | VAF 30/116 reads (26%) | catalogued as COSV100005900; called by muse, mutect2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCBLD1 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as rs531843493; called by muse, mutect2, varscan2
- DCHS1 | c.4828G>A p.E1610K | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486705624, COSV55033778; called by muse, mutect2
- DCHS1 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 137/436 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375936378; called by muse, mutect2, varscan2
- DCLRE1A | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767319245; called by muse, mutect2, varscan2
- DCP2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 38/178 reads (21%) | catalogued as COSV101203906; called by muse, mutect2, varscan2
- DDC | c.1277G>T p.R426I | Missense Mutation (SNP) | VAF 236/674 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV63566412; called by muse, mutect2, varscan2
- DDR2 | c.2021C>A p.S674Y | Missense Mutation (SNP) | VAF 134/451 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV63372276; called by muse, mutect2, varscan2
- DDX1 | c.2012C>A p.S671Y | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99246505; called by muse, mutect2
- DDX10 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV59433114; called by muse, mutect2, varscan2
- DDX18 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); catalogued as rs372688689, COSV54309134; called by muse, mutect2, varscan2
- DDX19A | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | catalogued as rs776793650, COSV56359512, COSV56360489; called by muse, mutect2, varscan2
- DDX23 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1210488388; called by muse, mutect2
- DDX24 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs745606556; called by muse, mutect2, varscan2
- DDX25 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs370940701; called by muse, mutect2, varscan2
- DEGS1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 91/377 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60379532; called by muse, mutect2, varscan2
- DENND10 | c.545G>T p.R182I | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63857366; called by muse, mutect2, varscan2
- DENND2B | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV100567900; called by muse, mutect2, varscan2
- DENND4C | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780075622, COSV66822089; called by muse, mutect2, varscan2
- DGKB | c.2325G>T p.K775N | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99336743; called by muse, varscan2
- DHFR2 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV58934172; called by muse, mutect2, varscan2
- DHX30 | c.2617C>T p.R873C (on ENST00000445061 / NM_138615.3; = p.R834C on NM_014966.3) | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53138042; called by muse, mutect2, varscan2
- DHX40 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs200066612, COSV52066666; called by muse, mutect2, varscan2
- DHX57 | c.3115C>T p.R1039* | Nonsense Mutation (SNP) | VAF 101/379 reads (27%) | catalogued as rs1450774084, COSV99769988; called by muse, mutect2, varscan2
- DIDO1 | c.4862C>T p.S1621L | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs745359035, COSV99826377; called by muse, mutect2, varscan2
- DISP1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 186/604 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs760562145, CM166807, COSV52658246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLG2 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1254449389, COSV101074340, COSV65841137; called by muse, mutect2
- DLGAP2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147195362; called by muse, mutect2, varscan2
- DLGAP2 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as rs762702813, COSV70098169; called by muse, mutect2, varscan2
- DMD | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 79/276 reads (29%) | catalogued as CM0910025, COSV99922561; called by muse, mutect2, varscan2
- DMXL2 | c.8770G>A p.V2924I | Missense Mutation (SNP) | VAF 129/535 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs748480363; called by muse, mutect2, varscan2
- DNA2 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs775240304, COSV63063043; called by muse, mutect2, varscan2
- DNAAF1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 178/577 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs538582505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.10114G>A p.E3372K (on ENST00000409039; = p.E3311K on NM_207437.3) | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs1018306646; called by muse, mutect2, varscan2
- DNAH11 | c.8062G>A p.A2688T | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs915888680; called by muse, mutect2, varscan2
- DNAH12 | c.9163C>A p.L3055I (on ENST00000351747; = p.L3923I on NM_001366028.2) | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61063682; called by muse, mutect2
- DNAH14 | c.1046G>A p.R349Q (on ENST00000445597; = p.R330Q on NM_001145154.3) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs563159604, COSV64784073; called by muse, mutect2, varscan2
- DNAH17 | c.10793C>T p.S3598L | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs537085638, COSV67757842; called by muse, mutect2, varscan2
- DNAH17 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372647934; called by muse, mutect2, varscan2
- DNAH5 | c.12250C>T p.R4084W | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752895938, COSV54255378; called by muse, mutect2, varscan2
- DNAH6 | c.9795C>A p.I3265= | Splice Region (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99404516; called by muse, varscan2
- DNAH7 | c.10045C>T p.R3349C | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs367980316; called by mutect2, varscan2
- DNAH8 | c.6639G>T p.E2213D | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547175; called by muse, mutect2
- DNAI1 | c.1992G>T p.K664N | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1380959008; called by muse, mutect2
- DNAJA2 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs1017561265; called by muse, mutect2
- DNAJB2 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1403156116, COSV60677912; called by muse, mutect2, varscan2
- DNAJB9 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 98/316 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV50812002; called by muse, mutect2, varscan2
- DNAJC3 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200036068; called by muse, mutect2, varscan2
- DNAJC6 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs779000495; called by muse, mutect2
- DOCK10 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as rs752177201, COSV51421316; called by muse, varscan2
- DOCK3 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | catalogued as COSV56522566; called by muse, mutect2, varscan2
- DOCK3 | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1273717275, COSV56533165; called by muse, mutect2, varscan2
- DOCK4 | c.3642G>T p.Q1214H | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV69854946; called by muse, mutect2
- DOP1A | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1468093035; called by muse, mutect2, varscan2
- DOP1B | c.4877G>A p.R1626Q | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs199678194, COSV101215710, COSV67692975; called by muse, mutect2, varscan2
- DPP10 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as COSV100064500; called by muse, mutect2, varscan2
- DPP10 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as COSV59686944; called by muse, varscan2
- DPP10 | c.2191C>A p.H731N | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771300943, COSV59697538; called by muse, mutect2, varscan2
- DPYD | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs777560627, COSV64603563; called by muse, mutect2, varscan2
- DPYD | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as rs80081766; called by muse, mutect2, varscan2
- DSC1 | c.1857G>A p.W619* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | catalogued as rs756441721; called by muse, mutect2, varscan2
- DSEL | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 74/247 reads (30%) | catalogued as COSV59489958; called by muse, mutect2, varscan2
- DSEL | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1312828647; called by muse, mutect2
- DSG4 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 133/434 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs369555342; called by muse, mutect2, varscan2
- DST | c.2239G>T p.E747* (on ENST00000361203 / NM_001374722.1; = p.E421* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 19/292 reads (7%) | catalogued as COSV55037959; called by muse, mutect2
- DTWD1 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.597); catalogued as rs764011116, COSV52071645; called by muse, mutect2, varscan2
- DTWD1 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52071055; called by muse, mutect2
- DUS4L-BCAP29 | c.1633T>G p.F545V | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs751312535; called by muse, mutect2, varscan2
- DYNC2I1 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 48/181 reads (27%) | catalogued as rs760704544; called by muse, mutect2, varscan2
- DYRK4 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201628488, COSV50537930, COSV50540502; called by muse, mutect2, varscan2
- DYTN | c.1049G>T p.R350I | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV71751932, COSV71752730; called by muse, mutect2, varscan2
- DZIP1L | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs199809396, COSV100551543, COSV59521946; called by muse, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, mutect2, varscan2
- ECEL1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs751317107, COSV58811768; called by muse, mutect2, varscan2
- ECT2 | c.620G>A p.R207Q (on ENST00000392692 / NM_001349098.2; = p.R176Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs148151130, COSV51688569; called by muse, mutect2, varscan2
- ECT2L | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 60/249 reads (24%) | catalogued as rs560012344, COSV57808467; called by muse, mutect2, varscan2
- EDA2R | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs868367275, COSV53630343; called by muse, mutect2, varscan2
- EFCAB5 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 43/148 reads (29%) | catalogued as rs374541486; called by muse, mutect2, varscan2
- EFCAB6 | c.3493G>A p.D1165N | Missense Mutation (SNP) | VAF 96/388 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs761394170; called by muse, mutect2, varscan2
- EFCAB7 | c.1877C>A p.S626Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs149784056, COSV100937634; called by muse, mutect2, varscan2
- EFHC1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769591944, COSV64136853; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EGF | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV54478139; called by muse, mutect2, varscan2
- EIF4A2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV56216956, COSV56217635, COSV99960966; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767295081, COSV100348981; called by muse, mutect2, varscan2
- EIF4G1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 142/515 reads (28%) | catalogued as COSV59989393; called by muse, mutect2, varscan2
- EIF4G3 | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs773049619, COSV99944162; called by muse, mutect2, varscan2
- ELF4 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 136/439 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs375750801; called by muse, mutect2, varscan2
- EML1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs757227237, COSV51752471; called by muse, mutect2, varscan2
- EML6 | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530391828, COSV62862999, COSV62866222; called by muse, mutect2, varscan2
- ENAH | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.209); catalogued as COSV52867313; called by muse, mutect2, varscan2
- ENPEP | c.896G>T p.R299I | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV54457890; called by muse, mutect2, varscan2
- ENPP1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 87/351 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs769645819, COSV62936334; called by muse, mutect2, varscan2
- EP400 | c.8453C>T p.P2818L | Missense Mutation (SNP) | VAF 134/467 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs754139537, COSV57778566; called by muse, mutect2, varscan2
- EPB41L2 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382957093, COSV61353484; called by muse, mutect2, varscan2
- EPB41L3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV104421719; called by muse, mutect2, varscan2
- EPC1 | c.758G>T p.R253I | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53925914; called by muse, mutect2, varscan2
- EPHA1 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775933608; called by muse, mutect2, varscan2
- EPHA4 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs927390651, COSV99917315; called by muse, mutect2
- EPPK1 | c.5080G>A p.V1694M | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs56005803, COSV73261951; called by muse, mutect2, varscan2
- ERAP2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as rs199510383; called by muse, mutect2, varscan2
- ERC2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs747730160, COSV55605679; called by muse, mutect2, varscan2
- ERCC6 | c.3213G>T p.E1071D | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs1171931512; called by muse, varscan2
- ERCC6 | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs373893264; called by muse, varscan2
- ERCC6L | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 52/244 reads (21%) | catalogued as COSV57819268; called by muse, mutect2, varscan2
- ERG | c.1069C>T p.R357C (on ENST00000398919 / NM_001243428.1; = p.R333C on NM_004449.4) | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333152977; called by muse, mutect2, varscan2
- ERICH3 | c.1364A>C p.K455T | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58604391; called by muse, mutect2, varscan2
- ERICH3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769315284, COSV58600498; called by muse, mutect2, varscan2
- ERN2 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs143641485; called by muse, mutect2
- ERVMER34-1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs372451410, COSV66920776; called by muse, varscan2
- ESX1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs144948361, COSV65424116; called by muse, mutect2, varscan2
- ETV1 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54151257; called by muse, mutect2, varscan2
- EVX2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 146/536 reads (27%) | catalogued as COSV57963938; called by muse, mutect2, varscan2
- EXD2 | c.676C>T p.R226C (on ENST00000312994 / NM_001193362.1; = p.R101C on NM_018199.3) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs762151815, COSV57278078, COSV57278257; called by muse, mutect2, varscan2
- EXOC6 | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV53322737; called by muse, mutect2, varscan2
- EXOC8 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV99149901; called by muse, mutect2, varscan2
- EXOSC2 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs771988501; called by muse, mutect2, varscan2
- EXPH5 | c.4615G>T p.E1539* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as rs200270555, COSV56202541, COSV56205262; called by muse, mutect2, varscan2
- EYA1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 16/416 reads (4%) | catalogued as COSV104411316, COSV58159549; called by muse, mutect2
- EYS | c.4710C>A p.F1570L | Missense Mutation (SNP) | VAF 145/423 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100425945; called by muse, mutect2, varscan2
- EYS | c.2722A>G p.M908V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs951142049; called by muse, mutect2, varscan2
- FABP3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs757091758, COSV60001553; called by muse, mutect2, varscan2
- FAM107B | c.260G>A p.R87Q (on ENST00000378458 / NM_001320737.1; = p.R262Q on NM_031453.3) | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs1421681819, COSV99473634; called by muse, mutect2, varscan2
- FAM122B | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99980170; called by muse, mutect2, varscan2
- FAM135B | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV52744513; called by muse, mutect2
- FAM170A | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100089450; called by muse, mutect2, varscan2
- FAM170A | c.987-1G>A p.X329_splice | Splice Site (SNP) | VAF 13/206 reads (6%) | catalogued as COSV100088996; called by muse, mutect2
- FAM178B | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1263047509, COSV100014374; called by muse, mutect2, varscan2
- FAM189A1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.683); catalogued as rs779222445, COSV54289428; called by muse, mutect2, varscan2
- FAM47A | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1479912221, COSV60496040; called by muse, mutect2
- FAM71E2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1057207469; called by muse, mutect2, varscan2
- FANCB | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs143585647, COSV60760611; called by muse, mutect2
- FANCD2 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 128/433 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249790407, COSV55034228; called by muse, varscan2
- FAT1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 49/217 reads (23%) | catalogued as COSV71672617; called by muse, mutect2, varscan2
- FAT4 | c.10261A>C p.I3421L | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as COSV58679007; called by muse, mutect2, varscan2
- FAT4 | c.11290C>A p.L3764I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.177); catalogued as COSV58693546; called by muse, mutect2
- FAT4 | c.13558C>T p.L4520F | Missense Mutation (SNP) | VAF 99/428 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1479758878, COSV58686685; called by muse, mutect2, varscan2
- FBN1 | c.4460-1G>T p.X1487_splice | Splice Site (SNP) | VAF 34/467 reads (7%) | catalogued as CS098578; called by muse, mutect2
- FBN1 | c.3209A>C p.D1070A | Missense Mutation (SNP) | VAF 22/727 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM020686, COSV57317979; called by muse, mutect2
- FBN3 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs377629999, COSV104374157; called by muse, mutect2, varscan2
- FBP2 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs770872181; called by muse, mutect2, varscan2
- FBXO11 | c.304C>T p.R102C (on ENST00000403359 / NM_001190274.2; = p.R18C on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1394743802, COSV57024268; called by muse, mutect2
- FBXW7 | c.1633T>G p.Y545D (on ENST00000281708 / NM_001349798.2; = p.Y465D on NM_018315.5) | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55898735; called by muse, mutect2, varscan2
- FEZ1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54026496; called by muse, mutect2, varscan2
- FGF13 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.905); catalogued as COSV65432774; called by muse, varscan2
- FGF17 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1490033943; called by muse, mutect2, varscan2
- FGFR1OP2 | c.254-1G>T p.X85_splice | Splice Site (SNP) | VAF 50/122 reads (41%) | catalogued as COSV57586269; called by muse, mutect2, varscan2
- FHDC1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561578259, COSV52597423; called by muse, mutect2, varscan2
- FHL5 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs147226482; called by muse, mutect2, varscan2
- FIG4 | c.2031C>A p.F677L | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV57786981; called by muse, mutect2, varscan2
- FKBP14 | c.84A>C p.K28N | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51652922; called by muse, mutect2, varscan2
- FMN1 | c.3205G>T p.E1069* (on ENST00000616417 / NM_001277313.2; = p.E846* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as COSV100569082; called by muse, mutect2, varscan2
- FMN2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 131/454 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1397813836, COSV60424392; called by muse, mutect2, varscan2
- FNDC1 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1217753633, COSV51935097; called by muse, mutect2, varscan2
- FOSB | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62278544; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs200318618, COSV58550443; called by muse, mutect2, varscan2
- FRMPD1 | c.4309G>T p.E1437* | Nonsense Mutation (SNP) | VAF 48/149 reads (32%) | catalogued as rs766220774; called by muse, mutect2, varscan2
- FRS2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV54724803; called by muse, mutect2, varscan2
- FRY | c.3337C>A p.L1113I | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV66567758; called by muse, mutect2
- FSIP2 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1050900207; called by muse, mutect2, varscan2
- FSIP2 | c.11702C>A p.S3901Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs925678859; called by muse, mutect2, varscan2
- FSIP2 | c.18764C>A p.S6255Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV58084529; called by muse, mutect2, varscan2
- FTCD | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 135/465 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201753824, COSV52426509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUBP1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs372081866; called by muse, mutect2, varscan2
- FZD10 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1201118563; called by muse, mutect2, varscan2
- G2E3 | c.1398C>A p.F466L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV52841849; called by muse, mutect2, varscan2
- G3BP1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as rs775783436, COSV62366085; called by muse, mutect2, varscan2
- GAB3 | c.1581G>T p.K527N | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV65820561; called by muse, mutect2, varscan2
- GABPA | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61397277; called by muse, mutect2
- GABRA2 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62919277; called by muse, mutect2, varscan2
- GABRA4 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 44/143 reads (31%) | catalogued as COSV51924068; called by muse, mutect2
- GABRR1 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 55/560 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1325732475, COSV101034086; called by muse, mutect2
- GALNT7 | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV53935201; called by muse, varscan2
- GBP4 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs759400322, COSV63252802; called by muse, mutect2, varscan2
- GCA | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as rs769512674; called by muse, mutect2, varscan2
- GCSAML | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs768814265, COSV63577072; called by muse, mutect2
- GFPT1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 22/354 reads (6%) | catalogued as COSV61950689; called by muse, mutect2
- GHR | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 102/408 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV50106072; called by muse, varscan2
- GIMAP1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1417844598, COSV100212349; called by muse, mutect2, varscan2
- GIMAP7 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57959710; called by muse, mutect2
- GIPC2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs762485885; called by muse, mutect2, varscan2
- GIPC3 | c.925C>T p.R309W (on ENST00000644946; = p.I304= on NM_133261.3) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs748777903, COSV59260277; called by muse, mutect2, varscan2
- GJB6 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1231348800, COSV53831748; called by muse, mutect2, varscan2
- GK | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 128/440 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV66734180; called by muse, mutect2, varscan2
- GLB1L | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 51/210 reads (24%) | catalogued as rs771057382, COSV55475876; called by muse, mutect2, varscan2
- GLI1 | c.3091G>T p.G1031* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV57362392; called by muse, mutect2, varscan2
- GLI2 | c.1470C>T p.F490= (on ENST00000361492 / NM_001374353.1; = p.F507= on NM_005270.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 22/65 reads (34%) | catalogued as rs544791528, COSV58035231; called by muse, mutect2, varscan2
- GLRA3 | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV56857597; called by muse, mutect2, varscan2
- GLRX2 | c.283A>G p.K95E (on ENST00000367439 / NM_197962.3; = p.K96E on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as rs34237236; called by muse, mutect2, varscan2
- GNL3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316204392; called by muse, varscan2
- GNPTAB | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs141007019; called by muse, mutect2, varscan2
- GNPTAB | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 91/352 reads (26%) | catalogued as COSV100172182, COSV54776682; called by muse, mutect2, varscan2
- GOLGA4 | c.2843A>C p.K948T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62709486; called by muse, mutect2, varscan2
- GOLGA6B | c.1955-1G>T p.X652_splice | Splice Site (SNP) | VAF 17/190 reads (9%) | catalogued as rs1388471871; called by muse, mutect2
- GOLT1A | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs868308808, COSV100383485; called by muse, mutect2
- GOPC | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs760440205, COSV99271124; called by muse, mutect2, varscan2
- GPAT3 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs747515668, COSV100022982; called by muse, mutect2, varscan2
- GPATCH8 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59194775; called by muse, mutect2
- GPC4 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63699575; called by muse, mutect2, varscan2
- GPD1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158808100; called by muse, mutect2
- GPR179 | c.1996G>A p.A666T (on ENST00000621958; = p.A665T on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as rs779762920; called by muse, mutect2, varscan2
- GPR20 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs763741808; called by muse, mutect2, varscan2
- GRIA4 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV56881329, COSV56887826; called by muse, mutect2, varscan2
- GRID2 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 40/125 reads (32%) | catalogued as COSV56253952; called by muse, mutect2, varscan2
- GRIFIN | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV70219137; called by muse, mutect2, varscan2
- GRIK2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59709996; called by muse, mutect2, varscan2
- GRIK4 | c.1167C>T p.I389= | Splice Region (SNP) | VAF 46/150 reads (31%) | catalogued as rs748528917, COSV101483581; called by muse, mutect2, varscan2
- GRIK4 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV101483684, COSV101483733; called by muse, mutect2, varscan2
- GRIK5 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs778914367, COSV53474560; called by muse, mutect2, varscan2
- GRIN2B | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1271239566; called by muse, mutect2
- GSC2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371048481; called by muse, mutect2
- GSDMC | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV52695623; called by muse, mutect2, varscan2
- GTF2E2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1209670862, COSV63478343; called by muse, mutect2, varscan2
- GUCA1B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 151/528 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751148469; called by muse, mutect2, varscan2
- GUCY2C | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs769797661, COSV53786630, COSV53797359; called by muse, varscan2
- GUK1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368879259; called by muse, mutect2, varscan2
- GYPE | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 74/216 reads (34%) | catalogued as rs775752453, COSV62263569; called by muse, mutect2, varscan2
- H2BC4 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58414879, COSV58417027; called by muse, mutect2, varscan2
- HAUS1 | c.739-1G>A p.X247_splice | Splice Site (SNP) | VAF 46/152 reads (30%) | catalogued as rs759810155, COSV56363321; called by muse, mutect2, varscan2
- HAUS6 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs761183330, COSV65841006; called by muse, mutect2, varscan2
- HCFC1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV60077862; called by muse, mutect2, varscan2
- HCN4 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs143339036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDX | c.1812C>A p.F604L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52974943; called by muse, mutect2, varscan2
- HEATR1 | c.2387T>G p.F796C | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs778995015; called by muse, mutect2, varscan2
- HECTD1 | c.6475C>A p.L2159I | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67949841; called by muse, mutect2, varscan2
- HEPHL1 | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as rs773360144, COSV59889886; called by muse, mutect2, varscan2
- HERC1 | c.7465C>A p.H2489N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV71246201; called by muse, mutect2, varscan2
- HERC4 | c.2677C>T p.R893W (on ENST00000395198 / NM_022079.3; = p.R885W on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99516469; called by muse, mutect2, varscan2
- HFM1 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as CM1514102, COSV54020865; called by muse, mutect2, varscan2
- HIPK4 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.542); catalogued as rs1326236017, COSV104390948; called by muse, mutect2
- HIRIP3 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs529203258, COSV99662943; called by muse, mutect2, varscan2
- HIVEP2 | c.4489C>T p.R1497* | Nonsense Mutation (SNP) | VAF 91/282 reads (32%) | catalogued as COSV50016872; called by muse, mutect2, varscan2
- HIVEP2 | c.3758C>T p.S1253L | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1242609751, COSV50023861; called by muse, varscan2
- HLA-DMB | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as rs892565761, COSV66870936; called by muse, varscan2
- HMCN1 | c.11377C>T p.R3793C | Missense Mutation (SNP) | VAF 119/428 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147547755, COSV54892188; called by muse, mutect2, varscan2
- HMG20A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1044909978; called by muse, mutect2, varscan2
- HMGCLL1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1233803980; called by muse, mutect2, varscan2
- HMGXB3 | c.3856G>A p.E1286K (on ENST00000613459; = p.E1040K on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.314); catalogued as rs1226903639, COSV53834272; called by muse, mutect2
- HMMR | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV62375625; called by muse, mutect2, varscan2
- HOXC12 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 142/449 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs777140619, COSV54535732; called by muse, mutect2, varscan2
- HPF1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 62/206 reads (30%) | catalogued as COSV66421701; called by muse, varscan2
- HPSE2 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 99/347 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs373432908; called by muse, mutect2, varscan2
- HPSE2 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65202902; called by muse, mutect2, varscan2
- HRH2 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 93/354 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as rs766825841; called by muse, mutect2, varscan2
- HS6ST1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 154/794 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs370343793; called by muse, varscan2
- HSD17B2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752344353, COSV52274074; called by muse, mutect2, varscan2
- HSP90AB1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs776369287; called by muse, mutect2
- HSPA4 | c.655A>C p.K219Q | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59182003; called by muse, mutect2, varscan2
- HSPH1 | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV60711028; called by muse, mutect2, varscan2
- HTR1A | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1479266939; called by muse, mutect2, varscan2
- HTR2C | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV52220085; called by muse, mutect2, varscan2
- HUNK | c.1862C>A p.S621Y | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99527931; called by muse, mutect2, varscan2
- HUS1B | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs779869323, COSV57866209; called by muse, mutect2, varscan2
- HYDIN | c.8096G>A p.R2699H | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs368332616; called by muse, mutect2, varscan2
- HYDIN | c.3826G>T p.E1276* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV66832260, COSV66834001; called by muse, mutect2, varscan2
- IARS2 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV56963826; called by muse, mutect2, varscan2
- ICAM4 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs758847209; called by muse, mutect2, varscan2
- ICE1 | c.6031C>T p.R2011C | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56831396; called by muse, mutect2
- IFIT1 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1005534310, COSV65661238; called by muse, mutect2, varscan2
- IFNA1 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.619); catalogued as COSV52806665; called by muse, mutect2, varscan2
- IFNA21 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV66518426, COSV66518456; called by muse, mutect2
- IFT80 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 127/449 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58446022; called by muse, varscan2
- IGF2R | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 54/174 reads (31%) | catalogued as COSV100807023; called by muse, mutect2, varscan2
- IGF2R | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs746398907; called by muse, mutect2, varscan2
- IGHV3-7 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs782746599; called by muse, mutect2
- IGKV1D-42 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs201243538; called by muse, mutect2, varscan2
- IGSF1 | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63838745, COSV99057198; called by muse, mutect2, varscan2
- IKBKG | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs179363896, CM045871; ClinVar: conflicting interpretations of pathogenicity / not provided; called by muse, mutect2, varscan2
- IL1RAPL2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 14/274 reads (5%) | catalogued as COSV61172496; called by muse, mutect2
- IL1RAPL2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.77); catalogued as rs751827217, COSV61155639, COSV61168151; called by muse, mutect2, varscan2
- IL23R | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as COSV104417015; called by muse, mutect2, varscan2
- IL5 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs755418324, COSV99185045; called by muse, mutect2, varscan2
- ILVBL | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289847615, COSV54617597, COSV54617804; called by muse, mutect2, varscan2
- IMPG1 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64055621; called by muse, mutect2, varscan2
- IMPG2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/229 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs1170802697; called by muse, mutect2, varscan2
- IPCEF1 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs772792412, COSV54550489; called by muse, mutect2, varscan2
- IPO8 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs778254539, COSV56240309; called by muse, mutect2, varscan2
- IQCG | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 66/266 reads (25%) | catalogued as rs1391475516; called by muse, varscan2
- IQGAP2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201291442, COSV57177499; called by muse, varscan2
- IRAK3 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 118/376 reads (31%) | catalogued as COSV99705978; called by muse, mutect2, varscan2
- IRS4 | c.3169G>A p.D1057N | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs886108400; called by muse, mutect2, varscan2
- ISM2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs374050496, COSV53634284; called by muse, mutect2, varscan2
- ITGB8 | c.2051G>T p.R684I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV56005131; called by muse, mutect2
- ITIH2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs377214728; called by muse, mutect2, varscan2
- ITIH4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs376828517; called by muse, mutect2, varscan2
- ITK | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV70063610; called by muse, varscan2
- ITK | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 129/456 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760650238, COSV70061019; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1495T>G p.F499V (on ENST00000439118 / NM_001008949.3; = p.F507V on NM_178495.6) | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV100742147; called by muse, varscan2
- ITSN2 | c.3979G>T p.E1327* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as rs1553341912; called by muse, mutect2
- IWS1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1420907215; called by muse, mutect2, varscan2
- IZUMO1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV99710519; called by muse, mutect2, varscan2
- JAK1 | c.2581C>A p.P861T | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs375979659; called by muse, mutect2, varscan2
- JRKL | c.809T>G p.F270C | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99567612; called by muse, mutect2, varscan2
- JSRP1 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1323743390; called by muse, mutect2, varscan2
- KALRN | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53777007; called by muse, mutect2, varscan2
- KANSL1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 104/641 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs752415137, COSV52269623; ClinVar: likely benign; called by muse, mutect2, varscan2
- KAT6A | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 33/451 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1320782499; called by muse, mutect2
- KATNAL1 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 51/228 reads (22%) | catalogued as rs1265045426, COSV66065176; called by muse, mutect2, varscan2
- KATNAL2 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375338531; called by muse, mutect2, varscan2
- KATNBL1 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99854501; called by muse, mutect2, varscan2
- KBTBD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 77/335 reads (23%) | catalogued as rs1330796361, COSV73241195; called by muse, mutect2, varscan2
- KCNA2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373042266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA3 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63902525; called by muse, mutect2, varscan2
- KCNAB1 | c.418G>A p.E140K (on ENST00000490337 / NM_172160.3; = p.E129K on NM_003471.3) | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919946760, COSV56740913; called by muse, mutect2, varscan2
- KCNH7 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs753644565, COSV59800819, COSV59808285; called by muse, mutect2, varscan2
- KCNIP1 | c.619C>A p.L207I (on ENST00000411494 / NM_001034837.3; = p.L196I on NM_014592.4) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61081530; called by muse, mutect2, varscan2
- KCNK5 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV63988936; called by muse, mutect2, varscan2
- KCNN4 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202202107, COSV99487051; called by muse, mutect2, varscan2
- KCNQ3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774311301, COSV66468995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5B | c.3841C>T p.R1281* | Nonsense Mutation (SNP) | VAF 56/223 reads (25%) | catalogued as rs866525850, COSV52507240; called by muse, mutect2, varscan2
- KDM5B | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.153); catalogued as rs766624254, COSV99349823; called by muse, mutect2, varscan2
- KEL | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 205/703 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs147489746; called by muse, mutect2, varscan2
- KERA | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.05); catalogued as COSV57131482; called by muse, mutect2, varscan2
- KIAA0319 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs770931600, COSV65500477; called by muse, mutect2, varscan2
- KIAA0586 | c.4234G>T p.E1412* (on ENST00000619416 / NM_001244190.2; = p.E1351* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 60/236 reads (25%) | catalogued as COSV54173001; called by muse, mutect2, varscan2
- KIAA0825 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754099690, COSV56950668; called by muse, mutect2, varscan2
- KIAA1109 | c.4040G>A p.R1347Q | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1447100926; called by muse, mutect2, varscan2
- KIDINS220 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 81/346 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs773095081, COSV56755745; called by muse, mutect2, varscan2
- KIF13A | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV52446598; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2
- KIF5A | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 133/448 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1376496207; called by muse, mutect2, varscan2
- KIT | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 154/509 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55398646; called by muse, mutect2, varscan2
- KLF3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs369311053, COSV54713245; called by muse, mutect2, varscan2
- KLHDC7B | c.155G>A p.G52D (on ENST00000395676; = p.G693D on NM_138433.5) | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.069); catalogued as rs1387058977; called by muse, mutect2, varscan2
- KLHL13 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.871); catalogued as COSV53247544; called by muse, mutect2, varscan2
- KLRC2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs562207630, COSV101122659; called by muse, mutect2, varscan2
- KMT2D | c.14737G>T p.E4913* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs1243355591; called by muse, mutect2, varscan2
- KMT2E | c.1952G>T p.R651I | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99995569, COSV99997329; called by muse, mutect2, varscan2
- KMT2E | c.4239G>T p.K1413N | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs766667530; called by muse, mutect2, varscan2
- KNL1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | catalogued as COSV61152771; called by muse, mutect2
- KNSTRN | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs1202900620; called by muse, mutect2, varscan2
- KPNA6 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs1557487789, COSV65359734; called by muse, mutect2, varscan2
- KRR1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 43/181 reads (24%) | catalogued as COSV104384832; called by muse, mutect2, varscan2
- KRT80 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV57550074; called by muse, mutect2, varscan2
- KRT84 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs1380114702; called by muse, mutect2, varscan2
- KRTAP10-7 | c.746C>A p.S249* | Nonsense Mutation (SNP) | VAF 160/531 reads (30%) | catalogued as COSV59110298; called by muse, mutect2, varscan2
- KRTAP16-1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs760350540; called by muse, mutect2, varscan2
- KRTAP6-3 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 86/258 reads (33%) | PolyPhen possibly damaging (0.833); catalogued as COSV66963459; called by muse, mutect2, varscan2
- L1CAM | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs782712766, CM046033, COSV62829971; called by muse, mutect2, varscan2
- L1CAM | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100648987; called by muse, mutect2
- LAMA1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 120/374 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs376345144; called by muse, mutect2, varscan2
- LAMA2 | c.7271C>A p.S2424* | Nonsense Mutation (SNP) | VAF 129/403 reads (32%) | catalogued as COSV70354983; called by muse, mutect2, varscan2
- LAMA3 | c.9404C>A p.S3135* (on ENST00000313654 / NM_198129.4; = p.S1526* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 129/499 reads (26%) | catalogued as COSV99335067; called by muse, mutect2, varscan2
- LAMP1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.92); catalogued as rs374678550; called by muse, mutect2, varscan2
- LAYN | c.279C>A p.F93L (on ENST00000375615 / NM_001258390.1; = p.F85L on NM_178834.5) | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as rs967508869; called by muse, mutect2, varscan2
- LCT | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs754374949, COSV51543821; called by mutect2, varscan2
- LECT2 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 53/180 reads (29%) | catalogued as rs138618187; called by muse, mutect2, varscan2
- LEO1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV104408223, COSV55175344; called by muse, mutect2, varscan2
- LGALS16 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV101236805; called by muse, mutect2, varscan2
- LGI1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs772228851, COSV65058047; called by muse, mutect2, varscan2
- LGSN | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs753479275, COSV65727386; called by muse, mutect2
- LHCGR | c.1567C>A p.L523I | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54298224; called by muse, mutect2
- LIG4 | c.2298C>A p.F766L | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV100799958; called by muse, mutect2
- LILRA2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764683666, COSV99253321; called by muse, mutect2, varscan2
- LILRB1 | c.300G>T p.K100N (on ENST00000427581; = p.K64N on NM_006669.6) | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100207043; called by muse, mutect2, varscan2
- LIMK2 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 41/140 reads (29%) | catalogued as rs114127458, COSV59181311; called by muse, mutect2, varscan2
- LIN7A | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs201514763, COSV99691594; called by muse, varscan2
- LIPF | c.210T>G p.N70K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as COSV99490694; called by muse, mutect2, varscan2
- LOXHD1 | c.4059C>A p.F1353L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV56066466; called by muse, mutect2
- LRCH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1470042897, COSV57747909; called by muse, mutect2, varscan2
- LRCH2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57762258; called by muse, mutect2
- LRFN5 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.638); catalogued as rs1188047844, COSV99984601; called by muse, mutect2, varscan2
- LRIF1 | c.1907A>C p.K636T | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.785); catalogued as rs151182141; called by muse, mutect2, varscan2
- LRP1B | c.1560G>T p.K520N | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs764810174; called by muse, mutect2
- LRRC40 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773947092, COSV100918873; called by muse, mutect2, varscan2
- LRRC40 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1479572346, COSV100918760; called by muse, mutect2, varscan2
- LRRC57 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294772975, COSV53001311, COSV53001541; called by muse, mutect2, varscan2
- LRRC6 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs957674260, COSV51538127; called by muse, mutect2, varscan2
- LRRC9 | c.4030C>T p.R1344* | Nonsense Mutation (SNP) | VAF 46/163 reads (28%) | catalogued as rs1387149899; called by muse, mutect2, varscan2
- LUZP4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1257167056, COSV64218871; called by muse, mutect2, varscan2
- LY75 | c.2627G>T p.R876I | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV55101880; called by muse, mutect2, varscan2
- LYST | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 102/436 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs558162561, COSV67703188, COSV67703578; called by muse, varscan2
- LYZL6 | c.29T>G p.V10G | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1175631950; called by muse, mutect2, varscan2
- MAB21L4 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs772783909, COSV56744682; called by muse, varscan2
- MACF1 | c.8777C>A p.S2926Y | Missense Mutation (SNP) | VAF 49/165 reads (30%) | catalogued as rs756026858, COSV57109039; called by muse, mutect2, varscan2
- MAGEB5 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66868655; called by muse, mutect2
- MAGI1 | c.3203C>T p.S1068L (on ENST00000402939 / NM_001033057.2; = p.S1097L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs574932979, COSV100439187; called by muse, mutect2, varscan2
- MAGI3 | c.3662C>T p.S1221L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.886); catalogued as rs770451764, COSV56843474; called by muse, mutect2, varscan2
- MAK | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100504684; called by muse, mutect2, varscan2
- MAK16 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 50/173 reads (29%) | catalogued as COSV64078034; called by muse, mutect2, varscan2
- MAML3 | c.1725G>T p.M575I | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100505250; called by muse, mutect2, varscan2
- MAMLD1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53376687; called by muse, mutect2, varscan2
- MAN2A2 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1384502446; called by muse, mutect2
- MAP1B | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs981718025; called by muse, mutect2, varscan2
- MAP7D2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 157/526 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.323); catalogued as COSV65525688; called by muse, varscan2
- MARCHF10 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs112642238; called by muse, mutect2, varscan2
- MARK3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53506254; called by muse, mutect2, varscan2
- MBNL3 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63730728; called by muse, mutect2, varscan2
- MBTPS2 | c.1066-1G>A p.X356_splice | Splice Site (SNP) | VAF 63/272 reads (23%) | catalogued as COSV65270269; called by muse, varscan2
- MCF2 | c.1680C>A p.F560L | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100644816; called by muse, mutect2, varscan2
- MCF2 | c.1486A>C p.K496Q | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV58494258; called by muse, mutect2, varscan2
- MCTP1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 59/195 reads (30%) | catalogued as rs751396813, COSV56505812; called by muse, varscan2
- MDC1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748459364, COSV64524834; called by muse, mutect2, varscan2
- MED13 | c.5272C>T p.R1758* | Nonsense Mutation (SNP) | VAF 75/246 reads (30%) | catalogued as COSV67263544; called by muse, mutect2, varscan2
- MGA | c.8201C>T p.S2734F (on ENST00000219905 / NM_001164273.1; = p.S2525F on NM_001080541.2) | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs990018401; called by muse, mutect2, varscan2
- MGME1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | catalogued as rs1257355538, COSV66624234; called by muse, mutect2
- MICAL2 | c.4964G>T p.R1655I | Missense Mutation (SNP) | VAF 78/276 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as rs1172453419, COSV56284490; called by muse, mutect2, varscan2
- MIGA1 | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as rs1206460593; called by muse, mutect2, varscan2
- MKX | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 45/147 reads (31%) | catalogued as COSV65391865; called by muse, mutect2, varscan2
- MLEC | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV57329397, COSV57329841; called by muse, mutect2, varscan2
- MLLT1 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs141047642; called by muse, mutect2, varscan2
- MMP12 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV58260230; called by muse, mutect2
- MMP12 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 134/217 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs183458117, COSV58260645, COSV58261545; called by muse, mutect2, varscan2
- MMP16 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54164848, COSV54176576; called by muse, varscan2
- MMP27 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1479338976, COSV52780164; called by muse, mutect2, varscan2
- MMP8 | c.956C>A p.S319Y | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52633469; called by muse, mutect2, varscan2
- MNDA | c.127T>G p.Y43D | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63740513; called by muse, varscan2
- MOG | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs756217285; called by muse, mutect2, varscan2
- MOGAT3 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | catalogued as COSV99777240; called by muse, mutect2, varscan2
- MORC1 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV51715146; called by muse, mutect2, varscan2
- MOXD1 | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs748046713, COSV99058030; called by muse, mutect2, varscan2
- MPP1 | c.1044C>A p.F348L | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs1557266668, COSV101053999, COSV65729877; called by muse, mutect2, varscan2
- MPPED1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68838962; called by muse, mutect2, varscan2
- MREG | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as rs1350233230; called by muse, mutect2, varscan2
- MRGPRD | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1049161913, COSV58422812; called by mutect2, varscan2
- MRGPRX1 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV100245970; called by muse, mutect2, varscan2
- MROH7 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 149/452 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as COSV59871492; called by muse, mutect2, varscan2
2,797 further variants in this file (1,779 protein-altering or splice-affecting, 574 silent, 444 other) are not listed here.
